Surgical pathology report (de-identified scan), TCGA case TCGA-61-2102, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2102-01A (Primary Tumor).

FINAL DIAGNOSIS:

FINAL DIAGNOSIS:

RIGHT ADNEXA:

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA OF OVARY WITH EXTENSIVE NECROSIS
- FALLOPIAN TUBE WITH PARATUBAL TUMOR DEPOSITS
- B) UTERUS WITH LEFT ADNEXA (60 GRAMS):
- CHRONIC CYSTIC CERVICITIS WITH SQUAMOUS METAPLASIA
- MYOMETRIUM WITH SEROSAL ADHESIONS CONTAINING METASTATIC ADENOCARCINOMA
- LEFT OVARY WITH METASTATIC PAPILLARY SEROUS ADENOCARCINOMA ON SURFACE
- LEFT FALLOPIAN TUBE WITH TUMOR DEPOSITS IN MESOSALPINX
- C) BIOPSY, SIGMOID:
- FIBROADIPOSE TISSUE WITH METASTATIC ADENOCARCINOMA
- D) APPENDIX:
- NOT REMARKABLE
- E) OMENTUM:
- ADIPOSE TISSUE WITH METASTATIC ADENOCARCINOMA
-

Source: NCI Genomic Data Commons file 8ae9983f-f2b3-4f9a-8ca3-0b04294820b5 (TCGA-61-2102.F0521E47-1CC3-4F72-9EFD-3D128F57E614.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).